Somatic mutation profile of tumor specimen TCGA-EE-A2GN-06A (aliquot TCGA-EE-A2GN-06A-11D-A196-08) from TCGA case TCGA-EE-A2GN, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 72.3 years (26,421 days).
Specimen TCGA-EE-A2GN-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6df7bc7b-49a0-4279-9858-a4c35ec4d1e7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EE-A2GN-10A (Blood Derived Normal), aliquot TCGA-EE-A2GN-10A-01D-A198-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6af3b85e-b29f-48ef-9e13-2c52ac4a4ac5

The open-access MAF lists 501 somatic variants for this specimen: 346 protein-altering or splice-affecting, 146 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 309, Silent 146, Nonsense Mutation 24, Splice Site 5, Intron 4, Frame Shift Del 3, RNA 3, Frame Shift Ins 3, 3'Flank 2, Splice Region 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 34/116 reads (29%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- PTEN | c.766G>T p.E256* | Nonsense Mutation (SNP) | VAF 10/22 reads (45%) | catalogued as rs121909228, CM981674, COSV64288912, COSV64292115, COSV64297607; ClinVar: pathogenic; called by mutect2, varscan2
- ABCA13 | c.686C>T p.S229F | Missense Mutation (SNP) | VAF 142/264 reads (54%) | SIFT tolerated (0.6); PolyPhen possibly damaging (0.771); catalogued as rs867087150, COSV70025591; called by muse, mutect2, varscan2
- ACADS | c.512G>A p.R171Q | Missense Mutation (SNP) | VAF 52/152 reads (34%) | SIFT tolerated (0.55); PolyPhen benign (0.007); catalogued as rs751618843; called by mutect2, varscan2
- ADAM18 | c.508C>T p.P170S | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs267601916, COSV55844457; called by muse, mutect2, varscan2
- ADAM28 | c.514G>A p.D172N | Missense Mutation (SNP) | VAF 16/23 reads (70%) | SIFT tolerated (0.37); PolyPhen benign (0.006); catalogued as COSV56097550; called by muse, mutect2, varscan2
- ADGRV1 | c.2534G>A p.R845K | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT tolerated (0.2); PolyPhen benign (0.279); catalogued as rs1295070679, COSV67978028; called by muse, mutect2, varscan2
- ADGRV1 | c.9728C>T p.S3243F | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.071); catalogued as rs1217710894, COSV67978032; called by muse, mutect2, varscan2
- AEBP1 | c.2566G>A p.G856R | Missense Mutation (SNP) | VAF 61/142 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1451981425, COSV56255233, COSV56258883; called by muse, mutect2, varscan2
- AFF1 | c.1738C>T p.P580S | Missense Mutation (SNP) | VAF 12/17 reads (71%) | SIFT tolerated (0.08); PolyPhen benign (0.021); catalogued as rs1455543655, COSV57116454; called by muse, mutect2, varscan2
- AHNAK | c.13589G>A p.G4530E | Missense Mutation (SNP) | VAF 35/63 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV57203048; called by muse, mutect2, varscan2
- AJAP1 | c.304C>T p.H102Y | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV65448731; called by muse, mutect2, varscan2
- AK7 | c.1248C>G p.N416K | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV50869155, COSV50869521; called by muse, mutect2, varscan2
- AKAP17A | c.974G>A p.R325K | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.17); PolyPhen benign (0.018); catalogued as COSV100002511, COSV58308111; called by muse, mutect2
- ALDH4A1 | c.1618C>T p.R540C | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs576534785, COSV51889931; called by mutect2, varscan2
- AMMECR1L | c.647G>A p.G216E | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV55759861; called by muse, mutect2, varscan2
- AMPD1 | c.341C>T p.T114I | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.266); catalogued as COSV62414949; called by muse, mutect2, varscan2
- AMPD2 | c.149C>T p.P50L | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0.026); catalogued as COSV56648271; called by muse, mutect2, varscan2
- ANK2 | c.9913C>T p.P3305S | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.015); catalogued as COSV52144641; called by muse, mutect2, varscan2
- ANKRD11 | c.6401G>A p.G2134E | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.96); catalogued as COSV56354360; called by muse, mutect2, varscan2
- ANKRD17 | c.4555G>A p.E1519K | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.025); catalogued as COSV100428761, COSV58214758, COSV58219516; called by muse, varscan2
- ANKRD6 | c.160C>T p.H54Y | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV60228550; called by muse, mutect2, varscan2
- ANKS1B | c.2887G>A p.E963K | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.453); catalogued as rs1334171524, COSV59114970; called by muse, mutect2, varscan2
- ANO2 | c.1471C>T p.R491* (on ENST00000356134 / NM_001278597.3; = p.R495* on NM_001278596.3) | Nonsense Mutation (SNP) | VAF 22/46 reads (48%) | catalogued as rs750547819, COSV59007007; called by mutect2, varscan2
- APOH | c.383G>A p.G128E | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52771226; called by muse, mutect2, varscan2
- APOL3 | c.415G>A p.E139K (on ENST00000349314 / NM_145640.2; = p.E68K on NM_014349.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 46/68 reads (68%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as rs773979990, COSV62579095; called by muse, mutect2, varscan2
- ARFGEF2 | c.3797C>T p.S1266F | Missense Mutation (SNP) | VAF 47/156 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); catalogued as COSV64210242; called by muse, mutect2, varscan2
- ASB5 | c.605G>A p.G202E | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV56668428; called by muse, mutect2, varscan2
- ASIC2 | c.232G>A p.E78K | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.926); catalogued as rs749146881, COSV63293686; called by mutect2, varscan2
- ASPA | c.649C>T p.P217S | Missense Mutation (SNP) | VAF 110/255 reads (43%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs925180640, COSV53979924; called by muse, mutect2, varscan2
- ATCAY | c.343G>A p.E115K | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT deleterious (0.05); PolyPhen benign (0.018); catalogued as rs763099910, COSV56654027; called by mutect2, varscan2
- ATF7IP | c.1195G>A p.E399K | Missense Mutation (SNP) | VAF 32/70 reads (46%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.272); catalogued as COSV53765876; called by muse, mutect2
- ATG9A | c.1493C>T p.A498V | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.192); catalogued as COSV54692616; called by muse, mutect2, varscan2
- BACE2 | c.620C>T p.P207L | Missense Mutation (SNP) | VAF 59/97 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57737173; called by muse, mutect2, varscan2
- BBS12 | c.1433C>T p.P478L | Missense Mutation (SNP) | VAF 31/60 reads (52%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.549); catalogued as rs577035373, COSV100044935, COSV58561257; called by muse, mutect2, varscan2
- BCL2L11 | c.13C>T p.P5S | Missense Mutation (SNP) | VAF 32/69 reads (46%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.998); catalogued as rs1250218441, COSV100427519; called by muse, mutect2, varscan2
- BCL2L11 | c.14C>T p.P5L | Missense Mutation (SNP) | VAF 32/68 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs749642894; called by muse, mutect2, varscan2
- BCL6B | c.1327G>A p.D443N | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.041); catalogued as rs747497128, COSV53426121; called by mutect2, varscan2
- BRINP2 | c.506G>A p.R169K | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT tolerated (0.65); PolyPhen benign (0.001); catalogued as COSV64175026, COSV64181319; called by muse, mutect2, varscan2
- C1S | c.1705G>A p.G569S | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61070007; called by muse, mutect2, varscan2
- C2orf78 | c.979C>T p.P327S | Missense Mutation (SNP) | VAF 31/52 reads (60%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.655); catalogued as COSV68516315; called by muse, mutect2, varscan2
- C3 | c.2974G>A p.E992K | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs966333745, COSV55568284, COSV55579699; called by muse, varscan2
- CACNA1E | c.6118G>A p.E2040K (on ENST00000367573 / NM_001205293.3; = p.E1997K on NM_000721.4) | Missense Mutation (SNP) | VAF 42/66 reads (64%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); catalogued as COSV100701281, COSV62381531; called by muse, mutect2, varscan2
- CANT1 | c.1027G>C p.G343R | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56604860; called by muse, mutect2, varscan2
- CAPRIN2 | c.3153G>C p.W1051C | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51830233; called by muse, mutect2, varscan2
- CASP14 | c.118G>A p.E40K | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT tolerated (0.8); PolyPhen benign (0.072); catalogued as COSV55664681; called by muse, mutect2, varscan2
- CBLIF | c.371-1G>A p.X124_splice | Splice Site (SNP) | VAF 8/22 reads (36%) | catalogued as COSV57237883; called by muse, mutect2, varscan2
- CCDC126 | c.394A>T p.R132* | Nonsense Mutation (SNP) | VAF 5/34 reads (15%) | catalogued as COSV56739076; called by mutect2, varscan2
- CCDC178 | c.1868G>A p.G623E | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1354494348, COSV55758215; called by muse, mutect2, varscan2
- CCDC61 | c.502C>T p.Q168* | Nonsense Mutation (SNP) | VAF 4/16 reads (25%) | catalogued as rs755524901; called by mutect2, varscan2
- CD163 | c.2692G>A p.G898R | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.936); catalogued as COSV63129198; called by muse, mutect2, varscan2
- CD19 | c.1202C>T p.P401L | Missense Mutation (SNP) | VAF 17/26 reads (65%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as COSV61187705; called by muse, mutect2, varscan2
- CDCA2 | c.1073C>T p.P358L | Missense Mutation (SNP) | VAF 54/91 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs144887977; called by muse, mutect2, varscan2
- CDK11B | c.1769C>T p.P590L | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as rs948513727; called by muse, mutect2, varscan2
- CDK11B | c.1768C>T p.P590S | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.146); catalogued as rs1294459593, COSV58337737; called by muse, mutect2, varscan2
- CELA2B | c.725G>A p.G242D | Missense Mutation (SNP) | VAF 46/94 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61600801; called by muse, varscan2
- CEP126 | c.2921C>T p.P974L | Missense Mutation (SNP) | VAF 54/124 reads (44%) | SIFT tolerated (0.21); PolyPhen benign (0.059); catalogued as COSV54821375; called by muse, varscan2
- CHD1 | c.4634C>T p.S1545F | Missense Mutation (SNP) | VAF 45/96 reads (47%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.564); catalogued as COSV52336569, COSV52340616; called by muse, mutect2, varscan2
- CHD7 | c.4334G>C p.R1445T | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.076); catalogued as COSV71106972; called by muse, mutect2, varscan2
- CHD9 | c.2302T>C p.F768L | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as COSV54607443, COSV54608494; called by muse, mutect2, varscan2
- CLPS | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 30/103 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV52565751; called by muse, mutect2, varscan2
- CNGB3 | c.2386G>A p.E796K | Missense Mutation (SNP) | VAF 35/69 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); catalogued as COSV60684280; called by muse, mutect2, varscan2
- CNOT10 | c.2020C>T p.H674Y | Missense Mutation (SNP) | VAF 61/119 reads (51%) | SIFT tolerated (0.1); PolyPhen benign (0.091); catalogued as COSV59389995; called by muse, mutect2, varscan2
- CNTNAP4 | c.3221G>A p.G1074E | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs1157798980, COSV56663753, COSV56698753; called by muse, mutect2, varscan2
- COBL | c.1111G>A p.G371R | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.915); catalogued as COSV54337423, COSV99471639; called by muse, mutect2
- COL15A1 | c.557C>T p.P186L | Missense Mutation (SNP) | VAF 39/47 reads (83%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as COSV66641105; called by muse, mutect2, varscan2
- COL19A1 | c.2024C>T p.P675L | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs1562221943, COSV59564803, COSV59571418; called by muse, mutect2, varscan2
- COL4A3 | c.2630G>A p.G877E | Missense Mutation (SNP) | VAF 28/55 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67412561; called by muse, mutect2, varscan2
- COL7A1 | c.2410G>A p.A804T | Missense Mutation (SNP) | VAF 38/54 reads (70%) | SIFT deleterious (0.01); PolyPhen benign (0.202); catalogued as COSV60390877; called by muse, mutect2, varscan2
- CPNE9 | c.1150G>A p.E384K | Missense Mutation (SNP) | VAF 29/54 reads (54%) | SIFT deleterious (0.01); PolyPhen benign (0.23); catalogued as rs777532331, COSV56067537; called by muse, mutect2, varscan2
- CSGALNACT1 | c.635G>A p.G212E | Missense Mutation (SNP) | VAF 78/146 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59973615; called by muse, varscan2
- CSNK2A2 | c.268C>T p.R90C | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT tolerated (0.36); PolyPhen benign (0.025); catalogued as rs1431525244, COSV52640977; called by mutect2, varscan2
- CSTL1 | c.152C>T p.S51F | Missense Mutation (SNP) | VAF 70/115 reads (61%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.694); catalogued as rs564671302, COSV55677604; called by muse, mutect2, varscan2
- CYLD | c.1162C>T p.L388F | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.671); catalogued as COSV61092809; called by muse, mutect2, varscan2
- CYP2A6 | c.782C>T p.P261L | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.24); catalogued as COSV56533599; called by muse, mutect2, varscan2
- CYP2B6 | c.1210A>G p.K404E | Missense Mutation (SNP) | VAF 38/90 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.027); catalogued as COSV57842377; called by muse, mutect2, varscan2
- CYP2C19 | c.323G>A p.R108K | Missense Mutation (SNP) | VAF 26/36 reads (72%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV64906698; called by muse, mutect2, varscan2
- CYYR1 | c.406C>T p.P136S | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.729); catalogued as COSV54827617; called by muse, mutect2, varscan2
- D2HGDH | c.1339G>A p.E447K | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated (0.42); PolyPhen benign (0.03); catalogued as rs1191249765, COSV58318986; called by muse, mutect2, varscan2
- DACT1 | c.2029C>T p.R677W | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs868334123, COSV60019297; called by muse, mutect2, varscan2
- DAW1 | c.1039G>A p.E347K | Missense Mutation (SNP) | VAF 31/60 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV59363580; called by mutect2, varscan2
- DAZAP1 | c.1096C>T p.P366S | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.404); catalogued as rs1332109246, COSV51831031; called by muse, mutect2, varscan2
- DBN1 | c.238T>C p.Y80H | Missense Mutation (SNP) | VAF 87/210 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52787455; called by muse, varscan2
- DDX19A | c.1072C>T p.Q358* | Nonsense Mutation (SNP) | VAF 15/35 reads (43%) | catalogued as COSV56358599; called by muse, mutect2, varscan2
- DGKB | c.2081G>A p.R694K | Missense Mutation (SNP) | VAF 32/136 reads (24%) | SIFT tolerated (0.87); PolyPhen benign (0.012); catalogued as COSV51761030; called by muse, mutect2, varscan2
- DLL3 | c.68A>G p.Q23R | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.775); catalogued as COSV52693157; called by muse, mutect2, varscan2
- DNAH11 | c.4931C>T p.A1644V | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.341); catalogued as COSV60938451; called by muse, mutect2
- DOCK1 | c.2087C>T p.P696L | Missense Mutation (SNP) | VAF 15/19 reads (79%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); catalogued as COSV54729133; called by muse, mutect2, varscan2
- DOCK3 | c.3563C>T p.S1188F | Missense Mutation (SNP) | VAF 61/108 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs868683773, COSV56501731; called by muse, varscan2
- DOP1B | c.4724C>T p.S1575F | Missense Mutation (SNP) | VAF 84/150 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.646); catalogued as COSV67691963; called by muse, mutect2, varscan2
- DPT | c.208G>A p.D70N | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.726); catalogued as COSV63189486; called by mutect2, varscan2
- DSCAM | c.1591C>T p.P531S | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV68020364; called by muse, mutect2, varscan2
- DSG3 | c.604G>A p.E202K | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs866204126, COSV57124037; called by muse, mutect2, varscan2
- E2F7 | c.2134C>T p.P712S | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0.14); catalogued as COSV59737037; called by muse, mutect2, varscan2
- ELSPBP1 | c.488G>A p.G163E | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.99); catalogued as COSV60412765; called by muse, mutect2, varscan2
- ENO3 | c.926C>T p.S309L | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.068); catalogued as rs762985992, COSV52776037; called by muse, mutect2, varscan2
- EPHA10 | c.77G>A p.G26E | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.817); catalogued as COSV60401922; called by muse, mutect2, varscan2
- EPHA5 | c.449C>T p.T150I | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56629976; called by muse, mutect2, varscan2
- EXT2 | c.1174-1G>A p.X392_splice (on ENST00000343631; = p.X425_splice on NM_000401.3) | Splice Site (SNP) | VAF 36/81 reads (44%) | catalogued as COSV59146550; called by muse, mutect2, varscan2
- F8 | c.4018C>T p.P1340S | Missense Mutation (SNP) | VAF 23/24 reads (96%) | SIFT tolerated (0.68); PolyPhen benign (0.001); catalogued as COSV64269481; called by muse, mutect2, varscan2
- FARS2 | c.848G>A p.G283E | Missense Mutation (SNP) | VAF 56/109 reads (51%) | SIFT tolerated (0.05); PolyPhen benign (0.322); catalogued as COSV51164425; called by muse, varscan2
- FAT2 | c.10010G>A p.G3337D | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1271621498, COSV55812828; called by muse, mutect2, varscan2
- FCRL6 | c.557G>A p.G186D | Missense Mutation (SNP) | VAF 36/49 reads (73%) | SIFT tolerated (0.13); PolyPhen benign (0.323); catalogued as COSV58939845; called by muse, mutect2, varscan2
- FGFR4 | c.1048G>A p.V350M | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52800464; called by muse, mutect2, varscan2
- FLG2 | c.2945G>A p.G982E | Missense Mutation (SNP) | VAF 135/217 reads (62%) | SIFT deleterious (0.01); PolyPhen benign (0.099); catalogued as rs1426438273, COSV66166507; called by muse, mutect2, varscan2
- FNIP2 | c.2344C>T p.R782W | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT tolerated (0.21); PolyPhen benign (0.409); catalogued as rs778657615, COSV52436328; called by mutect2, varscan2
- FSIP2 | c.18928G>A p.E6310K | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as rs1437197254, COSV58077790; called by mutect2, varscan2
- FUBP1 | c.809C>T p.S270L | Missense Mutation (SNP) | VAF 34/89 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53925805, COSV53926951; called by mutect2, varscan2
- GALK1 | c.666C>G p.I222M | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV56689256; called by muse, mutect2, varscan2
- GALNT9 | c.1808A>C p.H603P (on ENST00000328957 / NM_001122636.2; = p.H237P on NM_021808.3) | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.857); catalogued as rs368883972; called by muse, mutect2, varscan2
- GBP4 | c.1325C>T p.S442F | Missense Mutation (SNP) | VAF 85/176 reads (48%) | SIFT tolerated (0.14); PolyPhen benign (0.234); catalogued as COSV63252788; called by muse, mutect2, varscan2
- GLCE | c.920C>T p.S307F | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.741); catalogued as COSV55944239; called by muse, mutect2, varscan2
- GOLIM4 | c.1559C>T p.P520L | Missense Mutation (SNP) | VAF 46/193 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV58327747; called by muse, mutect2, varscan2
- GON4L | c.4798C>T p.R1600W | Missense Mutation (SNP) | VAF 20/33 reads (61%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs778351826, COSV55185823; called by muse, mutect2, varscan2
- GPAT4 | c.80T>A p.L27H | Missense Mutation (SNP) | VAF 65/107 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67840145; called by mutect2, varscan2
- GPHB5 | c.34G>A p.A12T | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); catalogued as COSV58485498; called by muse, mutect2, varscan2
- GPR37L1 | c.710C>T p.P237L | Missense Mutation (SNP) | VAF 44/69 reads (64%) | SIFT tolerated (0.2); PolyPhen benign (0.098); catalogued as COSV66161867; called by muse, mutect2, varscan2
- GRIN3A | c.1018G>A p.E340K | Missense Mutation (SNP) | VAF 22/26 reads (85%) | SIFT tolerated (0.08); PolyPhen benign (0.058); catalogued as rs145326290, COSV62450102; called by mutect2, varscan2
- GRM6 | c.722-1G>A p.X241_splice | Splice Site (SNP) | VAF 28/64 reads (44%) | catalogued as rs766594761, CS128396, COSV51433172, COSV51445043; called by muse, varscan2
- GTF3C3 | c.657A>T p.E219D | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.426); catalogued as COSV55830805; called by muse, mutect2, varscan2
- GZMK | c.115C>T p.P39S | Missense Mutation (SNP) | VAF 13/19 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50244046; called by muse, mutect2, varscan2
- HARS1 | c.1048G>A p.E350K | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.589); catalogued as COSV56905438; called by muse, mutect2, varscan2
- HECW2 | c.4129G>A p.E1377K | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV53648466, COSV53662828; called by mutect2, varscan2
- HFM1 | c.1255G>A p.E419K | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.479); catalogued as COSV54020696; called by mutect2, varscan2
- HLA-DOA | c.553G>A p.D185N | Missense Mutation (SNP) | VAF 51/130 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs765200524, COSV57713472; called by muse, mutect2, varscan2
- HMCN1 | c.7126T>A p.Y2376N | Missense Mutation (SNP) | VAF 25/34 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV54875114; called by muse, mutect2, varscan2
- HMCN1 | c.9971C>T p.P3324L | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.542); catalogued as COSV54875125; called by muse, mutect2, varscan2
- HTT | c.1460C>T p.P487L | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.003); catalogued as COSV61857168; called by muse, mutect2, varscan2
- ICAM4 | c.321G>A p.W107* | Nonsense Mutation (SNP) | VAF 7/15 reads (47%) | catalogued as COSV53423233; called by mutect2, varscan2
- IFT172 | c.2366G>A p.R789Q | Missense Mutation (SNP) | VAF 28/55 reads (51%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as rs148237432; called by mutect2, varscan2
- IL1B | c.752G>A p.G251E | Missense Mutation (SNP) | VAF 65/109 reads (60%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV54520992; called by muse, mutect2, varscan2
- IL1RAPL2 | c.1663G>A p.E555K | Missense Mutation (SNP) | VAF 32/36 reads (89%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as rs867269825, COSV61142160; called by mutect2, varscan2
- IMPG1 | c.1633C>T p.H545Y | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT tolerated (0.69); PolyPhen benign (0.177); catalogued as COSV64054040; called by muse, mutect2, varscan2
- IRAK3 | c.1325C>T p.T442I | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as COSV54159192; called by muse, mutect2, varscan2
- IRF3 | c.692C>T p.S231F | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.56); catalogued as rs763276449, COSV55862227; called by muse, mutect2, varscan2
- IRF6 | c.115C>T p.P39S | Missense Mutation (SNP) | VAF 30/114 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM022378, CM1010272, COSV65418637, COSV65419488; called by muse, mutect2, varscan2
- ITGB2 | c.1921G>A p.G641S (on ENST00000302347; = p.G617S on NM_000211.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs749135078, COSV56607546; called by muse, mutect2, varscan2
- JARID2 | c.2431C>T p.H811Y | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as COSV104421166, COSV59184913; called by muse, mutect2, varscan2
- KCNJ4 | c.1166A>C p.E389A | Missense Mutation (SNP) | VAF 32/110 reads (29%) | SIFT tolerated (0.31); PolyPhen benign (0.014); catalogued as COSV57856043; called by muse, mutect2, varscan2
- KIAA1109 | c.10234G>A p.D3412N | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.867); catalogued as rs868714536; called by muse, mutect2, varscan2
- KIF18A | c.1910C>T p.T637I | Missense Mutation (SNP) | VAF 33/72 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV54180852; called by muse, mutect2, varscan2
- KMT2A | c.6985C>T p.P2329S | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.003); catalogued as COSV63281586; called by muse, mutect2, varscan2
- KMT2D | c.3716C>T p.S1239F | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV56408985; called by muse, mutect2, varscan2
- KRT6B | c.397G>A p.G133R | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs1364435295, COSV52887096; called by mutect2, varscan2
- KRT84 | c.598C>T p.L200F | Missense Mutation (SNP) | VAF 22/43 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs758334149, COSV57770516; called by muse, mutect2, varscan2
- LAMA3 | c.9146G>A p.G3049E (on ENST00000313654 / NM_198129.4; = p.G1440E on NM_000227.6) | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.073); catalogued as COSV52535394; called by muse, mutect2, varscan2
- LCMT1 | c.634C>A p.L212I | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.895); catalogued as COSV66724046; called by muse, varscan2
- LGR4 | c.1169C>T p.S390F | Missense Mutation (SNP) | VAF 46/111 reads (41%) | SIFT deleterious (0.05); PolyPhen benign (0.01); catalogued as COSV64863355; called by muse, mutect2, varscan2
- LIPF | c.451C>T p.P151S | Missense Mutation (SNP) | VAF 39/55 reads (71%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV53282364; called by muse, mutect2, varscan2
- LIPI | c.739G>A p.D247N | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100753905, COSV60707749; called by muse, mutect2, varscan2
- LPA | c.193G>A p.E65K | Missense Mutation (SNP) | VAF 54/67 reads (81%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.988); catalogued as COSV60296154; called by muse, mutect2, varscan2
- LRIG1 | c.3154G>T p.A1052S | Missense Mutation (SNP) | VAF 46/98 reads (47%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.001); catalogued as COSV56236430; called by muse, varscan2
- LRP12 | c.277C>T p.Q93* | Nonsense Mutation (SNP) | VAF 33/64 reads (52%) | catalogued as rs1287412577, COSV52629936; called by mutect2, varscan2
- LRP1B | c.1808G>A p.G603D | Missense Mutation (SNP) | VAF 21/30 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1162119235, COSV67184429; called by muse, mutect2, varscan2
- LRRC52 | c.776G>A p.G259E | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV54231155; called by muse, mutect2, varscan2
- LY6G6C | c.176T>A p.V59D | Missense Mutation (SNP) | VAF 83/172 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.731); catalogued as rs1333928230, COSV65404453; called by muse, mutect2, varscan2
- LY6G6C | c.175G>A p.V59I | Missense Mutation (SNP) | VAF 80/166 reads (48%) | SIFT tolerated (0.33); PolyPhen benign (0.01); catalogued as rs755724989; called by muse, mutect2, varscan2
- LY75 | c.2869C>T p.P957S | Missense Mutation (SNP) | VAF 23/43 reads (53%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs758297475, COSV55101737; called by muse, mutect2, varscan2
- MAEL | c.484G>A p.E162K | Missense Mutation (SNP) | VAF 24/42 reads (57%) | SIFT tolerated (0.63); PolyPhen probably damaging (0.949); catalogued as COSV63303791, COSV63305496; called by mutect2, varscan2
- MAGEA3 | c.352C>T p.H118Y | Missense Mutation (SNP) | VAF 50/59 reads (85%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.552); catalogued as rs1556826261, COSV64755789, COSV64756223; called by mutect2, varscan2
- MAGI3 | c.2498C>A p.P833H | Missense Mutation (SNP) | VAF 43/103 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56827568; called by mutect2, varscan2
- MAN2B2 | c.449T>A p.V150D | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV53450399; called by muse, mutect2, varscan2
- MAPK1 | c.955C>T p.P319S | Missense Mutation (SNP) | VAF 27/100 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as COSV53184679; called by muse, varscan2
- MARF1 | c.2626C>T p.L876F | Missense Mutation (SNP) | VAF 31/60 reads (52%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.812); catalogued as COSV60019638; called by muse, mutect2, varscan2
- MBD1 | c.220C>T p.P74S | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.909); catalogued as rs1182748371; called by mutect2, varscan2
- MBNL1 | c.1018C>T p.P340S (on ENST00000282486 / NM_207293.2; = p.P334S on NM_021038.5 and 10 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 43/55 reads (78%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV56823541; called by muse, mutect2, varscan2
- MCF2 | c.1901G>A p.R634Q | Missense Mutation (SNP) | VAF 14/18 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs370241205, COSV58477236; called by mutect2, varscan2
- MCF2L2 | c.1346C>T p.S449F | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs772418125; called by muse, mutect2, varscan2
- MEFV | c.1330G>A p.G444R | Missense Mutation (SNP) | VAF 48/170 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.988); catalogued as COSV54818389; called by muse, mutect2, varscan2
- METTL4 | c.313C>T p.H105Y | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.055); catalogued as rs993396428, COSV55246724; called by mutect2, varscan2
- MFSD2B | c.356G>A p.G119D | Missense Mutation (SNP) | VAF 21/32 reads (66%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.808); catalogued as COSV57853831; called by muse, mutect2, varscan2
- MFSD4A | c.619C>T p.P207S | Missense Mutation (SNP) | VAF 25/40 reads (63%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV65655964; called by muse, mutect2, varscan2
- MIEF2 | c.170C>T p.P57L | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs777138849, COSV58943248; called by muse, mutect2, varscan2
- MLPH | c.1189A>G p.S397G | Missense Mutation (SNP) | VAF 25/43 reads (58%) | SIFT tolerated (0.05); PolyPhen benign (0.183); catalogued as COSV52817960; called by muse, mutect2, varscan2
- MROH2B | c.1681G>A p.E561K | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV68180822, COSV68182913; called by muse, mutect2, varscan2
- MTMR4 | c.2840C>T p.P947L | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0); catalogued as COSV60199230; called by muse, mutect2, varscan2
- MUC16 | c.10291G>A p.D3431N | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.092); catalogued as COSV67443076; called by muse, mutect2, varscan2
- MUC5B | c.5718C>G p.I1906M | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT tolerated (0.28); PolyPhen benign (0.056); catalogued as COSV71589916; called by muse, mutect2, varscan2
- MUC5B | c.10772C>T p.S3591F | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.03); catalogued as rs1374211534, COSV71589917; called by muse, mutect2, varscan2
- MUC5B | c.11098G>A p.A3700T | Missense Mutation (SNP) | VAF 69/133 reads (52%) | SIFT tolerated (0.15); PolyPhen benign (0.052); catalogued as rs761966007, COSV71589918; called by muse, mutect2, varscan2
- MUC5B | c.15013C>T p.P5005S | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.092); catalogued as COSV71589919; called by muse, mutect2
- MYH7B | c.2218C>T p.Q740* | Nonsense Mutation (SNP) | VAF 18/62 reads (29%) | catalogued as COSV53416311; called by muse, mutect2, varscan2
- MYH7B | c.3991G>A p.E1331K | Missense Mutation (SNP) | VAF 53/93 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.769); catalogued as COSV52676769; called by muse, mutect2, varscan2
- NCAPD2 | c.2302C>T p.P768S | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs972819783; called by muse, mutect2, varscan2
- NETO1 | c.440G>A p.G147E | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs267605254, COSV55001194; called by muse, mutect2, varscan2
- NEU4 | c.34C>T p.L12F (on ENST00000391969 / NM_001167602.3; = p.L24F on NM_080741.4) | Missense Mutation (SNP) | VAF 27/46 reads (59%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.656); catalogued as COSV57989459; called by muse, mutect2, varscan2
- NLRP3 | c.2141G>C p.C714S | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs1248885910, COSV60219437; called by muse, mutect2, varscan2
- NPAP1 | c.2558G>A p.G853E | Missense Mutation (SNP) | VAF 28/59 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.192); catalogued as rs1484594194, COSV61504140; called by muse, mutect2, varscan2
- NPFF | c.252G>A p.W84* | Nonsense Mutation (SNP) | VAF 33/89 reads (37%) | catalogued as rs1291398677; called by muse, mutect2, varscan2
- NPFF | c.251G>A p.W84* | Nonsense Mutation (SNP) | VAF 32/86 reads (37%) | catalogued as rs368603484; called by mutect2, varscan2
- NR2E1 | c.443C>T p.S148F | Missense Mutation (SNP) | VAF 9/9 reads (100%) | SIFT deleterious (0.05); PolyPhen benign (0.024); catalogued as rs1215464751; called by muse, mutect2
- OR10A6 | c.329C>T p.A110V | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as COSV59164434, COSV59166158; called by mutect2, varscan2
- OR10Q1 | c.887G>A p.S296N | Missense Mutation (SNP) | VAF 32/90 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.021); catalogued as rs904691643, COSV57469633; called by muse, mutect2, varscan2
- OR10Z1 | c.354G>A p.M118I | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV63523787, COSV63526315; called by muse, mutect2, varscan2
- OR2AK2 | c.331G>A p.E111K | Missense Mutation (SNP) | VAF 45/212 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV63547705; called by muse, mutect2, varscan2
- OR4C12 | c.721C>T p.H241Y | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV58859344; called by mutect2, varscan2
- OR4D9 | c.743C>T p.T248I | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.364); catalogued as COSV61434045; called by muse, mutect2, varscan2
- OR5F1 | c.122G>A p.G41E | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53545121; called by mutect2, varscan2
- OR6A2 | c.293C>T p.S98F | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV60265931; called by muse, mutect2, varscan2
- OR6C2 | c.194C>T p.S65F | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.767); catalogued as COSV59515501; called by muse, varscan2
- OR6C76 | c.809G>A p.G270E | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.966); catalogued as rs767441218, COSV60388539; called by mutect2, varscan2
- PARP8 | c.917C>T p.S306F | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.235); catalogued as COSV55855491; called by muse, mutect2, varscan2
- PCDHA2 | c.94C>T p.R32C | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.901); catalogued as rs1033929121, COSV65364356; called by muse, mutect2, varscan2
- PCDHB2 | c.1331C>T p.S444F | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); catalogued as COSV50564015; called by muse, varscan2
- PCDHGB2 | c.2129C>A p.A710E | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); catalogued as COSV53895197; called by muse, mutect2, varscan2
- PCP4L1 | c.58G>A p.E20K | Missense Mutation (SNP) | VAF 7/10 reads (70%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.953); catalogued as rs1253772768, COSV73440577; called by mutect2, varscan2
- PCSK6 | c.1275G>A p.M425I | Missense Mutation (SNP) | VAF 19/124 reads (15%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.983); catalogued as COSV59338051; called by muse, varscan2
- PDE2A | c.1154A>C p.K385T | Missense Mutation (SNP) | VAF 50/120 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.306); catalogued as COSV57801874; called by muse, mutect2, varscan2
- PDGFD | c.571T>G p.S191A | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.952); catalogued as COSV56368012; called by muse, mutect2, varscan2
- PEX11A | c.428C>T p.S143F | Missense Mutation (SNP) | VAF 38/135 reads (28%) | SIFT tolerated (0.23); PolyPhen benign (0.005); catalogued as COSV55582747; called by muse, mutect2, varscan2
- PI3 | c.119C>T p.P40L | Missense Mutation (SNP) | VAF 32/102 reads (31%) | SIFT tolerated (0.23); PolyPhen benign (0.039); catalogued as COSV54782808; called by muse, mutect2, varscan2
- PLEC | c.5905G>A p.E1969K (on ENST00000322810 / NM_201380.4; = p.E1859K on NM_000445.5) | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); catalogued as rs1401586689; called by muse, mutect2, varscan2
- PLEKHH3 | c.1511G>A p.G504E | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV52219511; called by muse, mutect2, varscan2
- PLXNB1 | c.6228+1G>A p.X2076_splice | Splice Site (SNP) | VAF 11/15 reads (73%) | catalogued as COSV56487403, COSV99602498; called by muse, mutect2, varscan2
- POU6F2 | c.215C>T p.S72L | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.024); catalogued as COSV68867228; called by mutect2, varscan2
- PPM1A | c.994C>T p.H332Y | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV57785368; called by muse, mutect2, varscan2
- PPP1R1B | c.565+1G>A p.X189_splice | Splice Site (SNP) | VAF 25/49 reads (51%) | catalogued as rs770841761, COSV54201434; called by muse, mutect2, varscan2
- PRH1 | c.400C>T p.Q134* | Nonsense Mutation (SNP) | VAF 13/43 reads (30%) | catalogued as COSV101457487; called by muse, mutect2, varscan2
- PRSS58 | c.139C>T p.H47Y | Missense Mutation (SNP) | VAF 12/16 reads (75%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV73488431; called by muse, mutect2, varscan2
- PSMD1 | c.2177C>T p.A726V | Missense Mutation (SNP) | VAF 41/111 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.222); catalogued as COSV58076066; called by muse, mutect2, varscan2
- PSME3IP1 | c.671C>T p.S224F | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV58428552; called by muse, mutect2, varscan2
- PTCH1 | c.2042C>T p.P681L | Missense Mutation (SNP) | VAF 39/46 reads (85%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV59461975; called by muse, mutect2, varscan2
- PTPN2 | c.895C>T p.P299S | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.758); catalogued as COSV58995150; called by muse, mutect2, varscan2
- RABGAP1 | c.2603T>A p.I868N | Missense Mutation (SNP) | VAF 22/27 reads (81%) | SIFT deleterious (0.04); PolyPhen benign (0.082); catalogued as COSV65379360; called by muse, varscan2
- RAPGEF5 | c.704G>A p.G235E (on ENST00000401957 / NM_001367602.2; = p.G538E on NM_012294.5) | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT tolerated (0.58); PolyPhen benign (0.017); catalogued as rs753921639, COSV59778569; called by muse, mutect2, varscan2
- RCSD1 | c.1105G>A p.E369K | Missense Mutation (SNP) | VAF 9/14 reads (64%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.154); catalogued as COSV63257769; called by muse, mutect2, varscan2
- RNF10 | c.1987G>A p.G663S | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT tolerated (0.67); PolyPhen benign (0.057); catalogued as COSV58043387; called by muse, mutect2, varscan2
- RNF213 | c.2347C>T p.R783C | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs1012522997, COSV60618683; called by mutect2, varscan2
- RNF213 | c.7513C>T p.H2505Y | Missense Mutation (SNP) | VAF 46/97 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.272); catalogued as COSV60389575; called by mutect2, varscan2
- RNF214 | c.1085T>G p.L362* | Nonsense Mutation (SNP) | VAF 26/80 reads (33%) | catalogued as COSV100327079, COSV56117538; called by muse, mutect2, varscan2
- RNF25 | c.391C>T p.P131S | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55305880; called by muse, mutect2, varscan2
- RRP12 | c.406C>T p.R136C | Missense Mutation (SNP) | VAF 19/24 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1196244979, COSV59664573; called by mutect2, varscan2
- RTL3 | c.1313G>A p.R438H | Missense Mutation (SNP) | VAF 12/14 reads (86%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs369311059, COSV58183086; called by mutect2, varscan2
- RTN1 | c.1039G>A p.G347R | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT tolerated (0.1); PolyPhen benign (0.012); catalogued as COSV50718640; called by muse, mutect2, varscan2
- RYR3 | c.4715G>A p.G1572E | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66800503; called by muse, mutect2, varscan2
- S100A13 | c.142C>T p.H48Y | Missense Mutation (SNP) | VAF 60/238 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as rs770083487, COSV52679564; called by muse, mutect2, varscan2
- SAMD7 | c.1306C>T p.P436S | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.51); PolyPhen benign (0.138); catalogued as COSV59416883; called by muse, mutect2
- SCARB1 | c.529G>A p.G177S | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.329); catalogued as rs760512991, COSV99909269; called by muse, mutect2, varscan2
- SCN11A | c.2497C>T p.Q833* | Nonsense Mutation (SNP) | VAF 18/50 reads (36%) | catalogued as COSV56565242; called by muse, mutect2
- SCN5A | c.1639G>A p.E547K | Missense Mutation (SNP) | VAF 21/33 reads (64%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.824); catalogued as COSV61115318; called by mutect2, varscan2
- SCN7A | c.4048C>T p.L1350F | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.249); catalogued as COSV69268221; called by muse, varscan2
- SCN9A | c.553C>T p.R185C | Missense Mutation (SNP) | VAF 40/78 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs202083986, COSV57599428; ClinVar: uncertain significance; called by mutect2, varscan2
- SDR16C5 | c.226G>A p.G76R | Missense Mutation (SNP) | VAF 37/108 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.451); catalogued as COSV58125268; called by muse, mutect2, varscan2
- SETBP1 | c.2087C>T p.P696L | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as COSV56312433, COSV56330409; called by mutect2, varscan2
- SGSM1 | c.2977G>A p.D993N (on ENST00000400359 / NM_001039948.4; = p.D932N on NM_133454.3) | Missense Mutation (SNP) | VAF 42/155 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV63082277; called by muse, mutect2, varscan2
- SLAMF6 | c.427C>T p.Q143* | Nonsense Mutation (SNP) | VAF 31/49 reads (63%) | catalogued as COSV63586364, COSV63588030; called by mutect2, varscan2
- SLC13A5 | c.812G>A p.W271* | Nonsense Mutation (SNP) | VAF 19/46 reads (41%) | catalogued as COSV53421546; called by muse, mutect2, varscan2
- SLC17A8 | c.1579G>A p.E527K | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.028); catalogued as rs755212082, COSV60121740; called by mutect2, varscan2
- SLC6A17 | c.1271C>T p.P424L | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.29); PolyPhen benign (0.102); catalogued as COSV58991168, COSV99045200; called by muse, mutect2
- SNCAIP | c.118G>A p.E40K | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as rs187795054, COSV54401827; called by mutect2, varscan2
- SNCB | c.181G>A p.E61K | Missense Mutation (SNP) | VAF 13/21 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs752407509, COSV59434415; called by muse, mutect2, varscan2
- SNX14 | c.397G>A p.V133I | Missense Mutation (SNP) | VAF 39/111 reads (35%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); catalogued as rs752628199; called by muse, mutect2, varscan2
- SOCS5 | c.479C>G p.S160C | Missense Mutation (SNP) | VAF 36/59 reads (61%) | SIFT deleterious (0); PolyPhen benign (0.332); catalogued as COSV60603630; called by muse, mutect2, varscan2
- SOHLH2 | c.776C>T p.A259V | Missense Mutation (SNP) | VAF 42/78 reads (54%) | SIFT tolerated (0.12); PolyPhen benign (0.055); catalogued as rs753718206, COSV65901030; called by muse, mutect2, varscan2
- SPEG | c.3991C>T p.Q1331* | Nonsense Mutation (SNP) | VAF 15/34 reads (44%) | catalogued as COSV56662640; called by muse, mutect2, varscan2
- SPEG | c.9215G>A p.G3072D | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56671550; called by muse, mutect2, varscan2
- SPEN | c.2533G>A p.E845K | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.257); catalogued as COSV65357439; called by muse, mutect2, varscan2
- SPINK5 | c.842G>A p.G281E | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT tolerated (0.3); PolyPhen benign (0.103); catalogued as COSV56248111; called by muse, mutect2, varscan2
- SRD5A3 | c.343C>T p.L115F | Missense Mutation (SNP) | VAF 30/64 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.257); catalogued as COSV51710912, COSV51711287; called by muse, mutect2, varscan2
- STAB2 | c.5284G>A p.D1762N | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.506); catalogued as COSV66333790; called by muse, mutect2, varscan2
- STIM2 | c.1486C>T p.P496S | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as COSV52835830; called by muse, mutect2, varscan2
- SUSD4 | c.608G>A p.G203E | Missense Mutation (SNP) | VAF 46/75 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs775824594, COSV59549648; called by muse, mutect2, varscan2
- SVIL | c.4645C>T p.P1549S (on ENST00000355867 / NM_021738.3; = p.P1123S on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/40 reads (78%) | SIFT deleterious (0.02); PolyPhen benign (0.254); catalogued as COSV63439511; called by muse, mutect2, varscan2
- SWT1 | c.709C>T p.P237S | Missense Mutation (SNP) | VAF 95/146 reads (65%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.476); catalogued as COSV62252727; called by muse, mutect2, varscan2
- SYNPO2 | c.797G>A p.R266K | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs746789296, COSV61106033; called by muse, mutect2, varscan2
- TBC1D19 | c.1279C>T p.P427S | Missense Mutation (SNP) | VAF 35/116 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV53514136; called by muse, varscan2
- TERB2 | c.428C>T p.S143F | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as COSV61650470; called by muse, mutect2, varscan2
- TEX14 | c.2731G>A p.E911K (on ENST00000240361 / NM_001201457.2; = p.E905K on NM_031272.5) | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT tolerated (0.24); PolyPhen benign (0.086); catalogued as rs1298414370, COSV53611338; called by muse, mutect2, varscan2
- TNFRSF8 | c.1637C>T p.P546L | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.157); catalogued as rs975730559, COSV55794278; called by muse, mutect2, varscan2
- TRMT61B | c.448C>T p.P150S | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.86); catalogued as COSV60257397; called by muse, mutect2, varscan2
- TRPV4 | c.1091C>T p.A364V | Missense Mutation (SNP) | VAF 23/40 reads (58%) | SIFT tolerated (0.1); PolyPhen benign (0.012); catalogued as COSV55679668; called by muse, mutect2, varscan2
- TSHZ2 | c.2924C>T p.S975L | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.46); PolyPhen benign (0.14); catalogued as rs267606003, COSV61586685; called by mutect2, varscan2
- TSPAN8 | c.136G>A p.E46K | Missense Mutation (SNP) | VAF 44/93 reads (47%) | SIFT tolerated (0.53); PolyPhen benign (0.139); catalogued as COSV56077326; called by muse, varscan2
- TTN | c.33439G>A p.E11147K (on ENST00000591111; = p.E10220K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/33 reads (24%) | PolyPhen benign (0.001); catalogued as rs963035255, COSV60369460; called by muse, mutect2, varscan2
- TTPAL | c.184C>T p.R62C | Missense Mutation (SNP) | VAF 16/25 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52828237; called by mutect2, varscan2
- TYK2 | c.202C>T p.P68S | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53384545; called by muse, mutect2, varscan2
- UBR2 | c.2300C>T p.P767L | Missense Mutation (SNP) | VAF 30/84 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.111); catalogued as COSV65748601; called by muse, mutect2, varscan2
- UGT1A7 | c.446C>T p.P149L | Missense Mutation (SNP) | VAF 75/126 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs368625224, COSV60852795; called by muse, mutect2, varscan2
- UGT2B28 | c.584C>T p.P195L | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV59430454; called by muse, mutect2, varscan2
- UNC13A | c.2581A>T p.I861F | Missense Mutation (SNP) | VAF 20/35 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV53187751; called by muse, mutect2, varscan2
- UNC5A | c.1260G>T p.E420D | Missense Mutation (SNP) | VAF 36/77 reads (47%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV56165189; called by mutect2, varscan2
- UNC79 | c.2983G>A p.D995N (on ENST00000393151 / NM_001346218.2; = p.D818N on NM_020818.5) | Missense Mutation (SNP) | VAF 64/145 reads (44%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.974); catalogued as COSV56372808; called by muse, mutect2, varscan2
- USP24 | c.3343C>T p.Q1115* | Nonsense Mutation (SNP) | VAF 7/12 reads (58%) | catalogued as COSV53761504; called by mutect2, varscan2
- USP6NL | c.1846C>T p.P616S | Missense Mutation (SNP) | VAF 20/30 reads (67%) | SIFT tolerated, low confidence (0.86); PolyPhen benign (0.001); catalogued as COSV53208942; called by muse, mutect2, varscan2
- VIRMA | c.5261C>T p.P1754L | Missense Mutation (SNP) | VAF 40/78 reads (51%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.723); catalogued as COSV52581496; called by muse, mutect2, varscan2
- VWC2L | c.355C>T p.H119Y | Missense Mutation (SNP) | VAF 14/22 reads (64%) | SIFT deleterious (0.01); PolyPhen benign (0.245); catalogued as COSV100436498, COSV56965208; called by mutect2, varscan2
- WDR54 | c.340G>A p.D114N | Missense Mutation (SNP) | VAF 45/72 reads (63%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.738); catalogued as COSV51961181; called by muse, mutect2, varscan2
- XIRP2 | c.6790G>A p.D2264N (on ENST00000628543; = p.D2439N on NM_152381.6) | Missense Mutation (SNP) | VAF 37/53 reads (70%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as rs563915541, COSV54679859; called by mutect2, varscan2
- ZFC3H1 | c.5074T>A p.F1692I | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV66435569; called by muse, mutect2, varscan2
- ZFP69B | c.586G>A p.E196K | Missense Mutation (SNP) | VAF 53/105 reads (50%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as COSV64314960; called by muse, mutect2, varscan2
- ZMAT3 | c.697C>T p.P233S | Missense Mutation (SNP) | VAF 28/38 reads (74%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.994); catalogued as COSV60992077; called by muse, varscan2
- ZNF135 | c.157G>A p.V53M | Missense Mutation (SNP) | VAF 52/125 reads (42%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.69); catalogued as rs1232317197, COSV57880005; called by muse, mutect2, varscan2
- ZNF195 | c.755C>T p.S252F (on ENST00000399602 / NM_001130520.3; = p.S180F on NM_007152.5) | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as rs267602860, COSV50001727; called by muse, mutect2, varscan2
- ZNF217 | c.91C>T p.P31S | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV56593703, COSV56603690; called by muse, varscan2
- ZNF35 | c.611G>A p.S204N | Missense Mutation (SNP) | VAF 80/134 reads (60%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs1559485111, COSV56075810; called by muse, mutect2, varscan2
- ZNF385D | c.835G>A p.E279K | Missense Mutation (SNP) | VAF 40/77 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV55745628; called by muse, mutect2, varscan2
- ZNF556 | c.911G>A p.R304Q | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.29); PolyPhen benign (0.091); catalogued as rs542573466, COSV56910771; called by mutect2, varscan2
- ZNF568 | c.898C>T p.H300Y | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747712951, COSV61740390; called by mutect2, varscan2
- ZNF629 | c.1939C>T p.Q647* | Nonsense Mutation (SNP) | VAF 4/12 reads (33%) | catalogued as COSV52697320; called by mutect2, varscan2
- ZNF709 | c.46G>A p.E16K | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV67194096; called by muse, mutect2, varscan2
- ZNF791 | c.368C>T p.T123I | Missense Mutation (SNP) | VAF 64/151 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.028); catalogued as COSV58479903; called by muse, mutect2, varscan2
- ZRANB2 | c.172G>A p.E58K | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.899); catalogued as COSV54670683; called by muse, mutect2, varscan2
- ZSCAN1 | c.566G>A p.R189K | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as COSV56601399; called by muse, mutect2, varscan2
- ZSCAN29 | c.2066G>A p.R689Q | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0.204); catalogued as rs557989661, COSV67822093; called by muse, mutect2, varscan2
- ZSWIM2 | c.433G>A p.D145N | Missense Mutation (SNP) | VAF 50/94 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54573701; called by muse, mutect2, varscan2
- AHNAK | c.8954dup p.P2986Afs*6 | Frame Shift Ins (INS) | VAF 24/74 reads (32%) | called by mutect2, pindel, varscan2
- AMPD2 | c.148C>T p.P50S | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (0.67); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ARRDC4 | c.1088C>T p.S363F | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.305); called by muse, mutect2, varscan2
- ATM | c.494_496+2dup | Frame Shift Ins (INS) | VAF 22/62 reads (35%) | called by mutect2, varscan2
- ATMIN | c.1490G>A p.G497E | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.33); PolyPhen benign (0.001); called by muse, varscan2
- BAZ2B | c.1744C>T p.H582Y | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.121); called by mutect2, varscan2
- BRD7 | c.1346dup p.L449Ffs*14 | Frame Shift Ins (INS) | VAF 14/38 reads (37%) | called by mutect2, pindel, varscan2
- C4orf33 | c.559C>T p.P187S | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CEP135 | c.3010A>C p.R1004= | Splice Region (SNP) | VAF 7/20 reads (35%) | called by muse, mutect2, varscan2
- COL4A6 | c.3953C>T p.P1318L | Missense Mutation (SNP) | VAF 14/19 reads (74%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- COL4A6 | c.3952C>A p.P1318T | Missense Mutation (SNP) | VAF 13/18 reads (72%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.867); called by mutect2, varscan2
- CTPS1 | c.449C>T p.T150I | Missense Mutation (SNP) | VAF 41/100 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- EFHC1 | c.1634C>A p.A545E | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- EIF3K | c.574C>T p.Q192* | Nonsense Mutation (SNP) | VAF 31/63 reads (49%) | called by muse, mutect2, varscan2
- EIF4G1 | c.293C>T p.A98V | Missense Mutation (SNP) | VAF 31/62 reads (50%) | SIFT tolerated (0.63); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- FZD2 | c.1035G>A p.W345* | Nonsense Mutation (SNP) | VAF 11/48 reads (23%) | called by muse, mutect2, varscan2
- FZD2 | c.1036G>A p.V346I | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- GTPBP2 | c.1439G>A p.G480E | Missense Mutation (SNP) | VAF 62/142 reads (44%) | SIFT tolerated (0.61); PolyPhen benign (0.424); called by muse, mutect2, varscan2
- GTPBP2 | c.1438G>A p.G480R | Missense Mutation (SNP) | VAF 62/138 reads (45%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.605); called by mutect2, varscan2
- IGHV5-51 | c.311G>A p.S104N | Missense Mutation (SNP) | VAF 67/110 reads (61%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IL1RL2 | c.259T>G p.W87G | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- KIF13A | c.4859C>T p.S1620L | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.003); called by mutect2, varscan2
- KIF21A | c.1089A>T p.K363N | Missense Mutation (SNP) | VAF 40/126 reads (32%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KIF21A | c.1088A>T p.K363I | Missense Mutation (SNP) | VAF 36/123 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LAMA3 | c.9145G>A p.G3049R (on ENST00000313654 / NM_198129.4; = p.G1440R on NM_000227.6) | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.106); called by mutect2, varscan2
- LMO7 | c.4693G>A p.G1565S (on ENST00000357063; = p.G1246S on NM_005358.5) | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.35); PolyPhen benign (0.182); called by mutect2, varscan2
- LMO7 | c.4694G>A p.G1565D (on ENST00000357063; = p.G1246D on NM_005358.5) | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); called by mutect2, varscan2
- NPC1 | c.3738_3747del p.L1247Tfs*2 | Frame Shift Del (DEL) | VAF 8/36 reads (22%) | called by mutect2, pindel, varscan2
- PCDHGC4 | c.2230C>A p.P744T | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.33); PolyPhen benign (0.011); called by mutect2, varscan2
- PLEKHH3 | c.1510G>A p.G504R | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0.169); called by muse, mutect2, varscan2
- PLXNB1 | c.6228G>A p.W2076* | Nonsense Mutation (SNP) | VAF 12/16 reads (75%) | called by muse, mutect2
- RFPL2 | c.812C>T p.T271I | Missense Mutation (SNP) | VAF 33/50 reads (66%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- SPEG | c.9214G>A p.G3072S | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- SPTAN1 | c.139C>T p.Q47* | Nonsense Mutation (SNP) | VAF 63/70 reads (90%) | called by mutect2, varscan2
- TDRD9 | c.3232C>T p.L1078F | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- WDR1 | c.440_441del p.K147Sfs*21 | Frame Shift Del (DEL) | VAF 5/26 reads (19%) | called by mutect2, pindel, varscan2
- ZNF197 | c.2385_2386del p.C795Wfs*24 | Frame Shift Del (DEL) | VAF 16/74 reads (22%) | called by pindel, varscan2
- ZNF592 | c.1269_1273delinsAAATT p.D424_E425delinsN* | Nonsense Mutation (ONP) | VAF 3/30 reads (10%) | called by muse*, mutect2*, pindel, varscan2*
- ZNF695 | c.319C>T p.Q107* | Nonsense Mutation (SNP) | VAF 118/190 reads (62%) | called by muse, mutect2, varscan2
- ZSCAN29 | c.1817G>A p.G606D | Missense Mutation (SNP) | VAF 35/106 reads (33%) | SIFT tolerated (0.63); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZZEF1 | c.4643C>T p.P1548L | Missense Mutation (SNP) | VAF 42/102 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.472); called by muse, mutect2, varscan2
- AC011448.1 | c.519C>T p.F173= | Silent (SNP) | VAF 12/22 reads (55%) | catalogued as rs866229338, COSV52272421; called by muse, mutect2, varscan2
- ACADS | c.513G>A p.R171= | Silent (SNP) | VAF 53/161 reads (33%) | called by muse, mutect2, varscan2
- ADD2 | c.135C>T p.F45= | Silent (SNP) | VAF 39/57 reads (68%) | catalogued as COSV52454418; called by mutect2, varscan2
- ALDH1L1 | c.2470C>T p.L824= | Silent (SNP) | VAF 21/35 reads (60%) | catalogued as COSV56410434; called by muse, mutect2, varscan2
- ARHGEF7 | c.1179C>T p.S393= (on ENST00000375741 / NM_001113511.2; = p.S215= on NM_003899.5 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 16/70 reads (23%) | catalogued as COSV54538507; called by muse, mutect2, varscan2
- ARID2 | c.366T>G p.L122= | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as COSV57595313; called by muse, mutect2, varscan2
- ARMC9 | c.1221C>T p.Y407= | Silent (SNP) | VAF 150/259 reads (58%) | catalogued as rs765726557, COSV63019291; called by muse, mutect2, varscan2
- ASXL3 | c.2922C>T p.I974= | Silent (SNP) | VAF 5/14 reads (36%) | catalogued as COSV52456558; called by muse, mutect2, varscan2
- ATF7IP | c.1197A>G p.E399= | Silent (SNP) | VAF 30/68 reads (44%) | catalogued as COSV53765901; called by muse, mutect2
- ATMIN | c.1491G>A p.G497= | Silent (SNP) | VAF 16/50 reads (32%) | called by muse, varscan2
- B4GALT5 | c.1027C>T p.L343= | Silent (SNP) | VAF 12/45 reads (27%) | catalogued as rs768971378; called by mutect2, varscan2
- BAZ2B | c.1743C>T p.S581= | Silent (SNP) | VAF 23/91 reads (25%) | called by muse, mutect2, varscan2
- BIRC6 | c.13179G>A p.R4393= | Silent (SNP) | VAF 68/186 reads (37%) | catalogued as COSV70195345; called by muse, varscan2
- BRMS1 | c.450G>A p.L150= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as COSV60819633; called by mutect2, varscan2
- C10orf71 | c.705C>T p.F235= | Silent (SNP) | VAF 11/11 reads (100%) | catalogued as COSV60504195; called by muse, mutect2, varscan2
- C4B | c.3885C>T p.F1295= | Silent (SNP) | VAF 10/29 reads (34%) | catalogued as COSV70313256; called by mutect2, varscan2
- C8orf74 | c.783C>T p.A261= | Silent (SNP) | VAF 10/35 reads (29%) | catalogued as rs376552859; called by muse, mutect2, varscan2
- C8orf76 | c.225G>A p.Q75= | Silent (SNP) | VAF 14/64 reads (22%) | catalogued as COSV52689737, COSV99415081; called by muse, mutect2, varscan2
- CACNA1B | c.5191C>A p.R1731= | Silent (SNP) | VAF 4/39 reads (10%) | catalogued as COSV53112622, COSV53129874; called by mutect2, varscan2
- CACNA1E | c.6783C>T p.G2261= (on ENST00000367573 / NM_001205293.3; = p.G2218= on NM_000721.4) | Silent (SNP) | VAF 5/20 reads (25%) | catalogued as COSV62381538; called by muse, mutect2, varscan2
- CACNG4 | c.471C>T p.I157= | Silent (SNP) | VAF 47/140 reads (34%) | catalogued as rs1237740903, COSV50924095; called by muse, mutect2, varscan2
- CCDC61 | c.501C>G p.G167= | Silent (SNP) | VAF 4/17 reads (24%) | catalogued as rs750989563; called by muse, mutect2, varscan2
- CCDC63 | c.1230G>A p.L410= | Silent (SNP) | VAF 11/31 reads (35%) | catalogued as rs778921953, COSV57526728; called by mutect2, varscan2
- CD300A | c.258C>T p.F86= | Silent (SNP) | VAF 16/40 reads (40%) | catalogued as COSV60409456; called by mutect2, varscan2
- CEACAM19 | c.474C>T p.I158= | Silent (SNP) | VAF 51/167 reads (31%) | catalogued as rs866413746, COSV62551786; called by muse, mutect2, varscan2
- COL11A2 | c.3714G>A p.E1238= (on ENST00000341947 / NM_080680.3; = p.E1131= on NM_080679.2) | Silent (SNP) | VAF 17/55 reads (31%) | catalogued as rs758540775, COSV59493375; called by muse, mutect2, varscan2
- COL22A1 | c.12C>T p.L4= | Silent (SNP) | VAF 6/9 reads (67%) | called by mutect2, varscan2
- CRB1 | c.3915G>T p.P1305= | Silent (SNP) | VAF 41/147 reads (28%) | catalogued as COSV66328593; called by muse, mutect2, varscan2
- CTPS1 | c.450C>T p.T150= | Silent (SNP) | VAF 42/99 reads (42%) | catalogued as rs779429212, COSV65451867; called by mutect2, varscan2
- CYP2A13 | c.1155C>T p.L385= | Silent (SNP) | VAF 9/27 reads (33%) | catalogued as COSV57836248; called by muse, mutect2, varscan2
- CYP4A22 | c.999C>T p.I333= | Silent (SNP) | VAF 5/25 reads (20%) | catalogued as COSV53737912; called by mutect2, varscan2
- DDX3X | c.669C>T p.A223= (on ENST00000399959; = p.A224= on NM_001356.5) | Silent (SNP) | VAF 12/14 reads (86%) | called by muse, varscan2
- DLEC1 | c.1812G>A p.Q604= | Silent (SNP) | VAF 52/86 reads (60%) | catalogued as COSV57294796; called by muse, mutect2, varscan2
- DMBT1 | c.7602C>T p.P2534= (on ENST00000338354 / NM_001377530.1; = p.P1777= on NM_004406.3) | Silent (SNP) | VAF 10/11 reads (91%) | catalogued as COSV57533652; called by muse, varscan2
- DNM2 | c.1797C>T p.D599= (on ENST00000355667 / NM_001005360.3; = p.D595= on NM_004945.3) | Silent (SNP) | VAF 6/44 reads (14%) | catalogued as COSV58956874; called by mutect2, varscan2
- DNMT3B | c.525G>A p.E175= | Silent (SNP) | VAF 24/68 reads (35%) | catalogued as COSV52414755, COSV99143307; called by muse, varscan2
- EFCAB6 | c.3634C>T p.L1212= | Silent (SNP) | VAF 22/104 reads (21%) | called by muse, mutect2, varscan2
- EFCAB6 | c.3633C>T p.I1211= | Silent (SNP) | VAF 23/105 reads (22%) | called by muse, mutect2, varscan2
- EFHC1 | c.1635A>C p.A545= | Silent (SNP) | VAF 14/37 reads (38%) | called by muse, mutect2, varscan2
- EIF4G1 | c.294C>T p.A98= | Silent (SNP) | VAF 30/60 reads (50%) | called by muse, mutect2, varscan2
- EPHA6 | c.2841C>T p.F947= | Silent (SNP) | VAF 32/62 reads (52%) | catalogued as COSV67558202; called by muse, varscan2
- EVC2 | c.612C>T p.L204= | Silent (SNP) | VAF 33/67 reads (49%) | catalogued as rs1317049169, COSV60387546; called by muse, mutect2, varscan2
- FAH | c.1035C>T p.L345= | Silent (SNP) | VAF 9/45 reads (20%) | catalogued as CD128629; called by muse, mutect2, varscan2
- FAHD2B | c.816G>A p.G272= | Silent (SNP) | VAF 18/27 reads (67%) | catalogued as COSV55629873; called by muse, mutect2, varscan2
- FAM155A | c.1348C>T p.L450= | Silent (SNP) | VAF 28/60 reads (47%) | catalogued as COSV65548132; called by muse, varscan2
- FKBP9 | c.507G>A p.V169= | Silent (SNP) | VAF 10/58 reads (17%) | catalogued as COSV54227306; called by mutect2, varscan2
- FOXI1 | c.621C>T p.F207= | Silent (SNP) | VAF 24/48 reads (50%) | catalogued as rs532647880, COSV60387918; called by mutect2, varscan2
- FRAS1 | c.8217G>A p.A2739= | Silent (SNP) | VAF 7/28 reads (25%) | catalogued as rs917598012, COSV53650891; called by mutect2, varscan2
- FSTL5 | c.1392G>A p.V464= | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as COSV60180328; called by mutect2, varscan2
- FXR2 | c.1425C>T p.T475= | Silent (SNP) | VAF 10/28 reads (36%) | catalogued as COSV51467405; called by muse, mutect2, varscan2
- GABPB2 | c.636C>T p.A212= | Silent (SNP) | VAF 59/96 reads (61%) | catalogued as COSV64460456; called by muse, mutect2, varscan2
- GBF1 | c.2688G>A p.R896= (on ENST00000369983 / NM_001377137.1; = p.R895= on NM_004193.3) | Silent (SNP) | VAF 38/49 reads (78%) | catalogued as COSV64142591; called by muse, mutect2, varscan2
- GNAQ | c.31C>T p.L11= | Silent (SNP) | VAF 18/31 reads (58%) | catalogued as rs1156602302, COSV54106550; called by muse, mutect2, varscan2
- GRM6 | c.1965C>T p.L655= | Silent (SNP) | VAF 12/20 reads (60%) | catalogued as COSV51433166; called by muse, mutect2, varscan2
- GRM7 | c.1923C>T p.I641= | Silent (SNP) | VAF 28/83 reads (34%) | catalogued as COSV63128562; called by mutect2, varscan2
- GSR | c.861G>A p.V287= | Silent (SNP) | VAF 28/50 reads (56%) | catalogued as COSV55319155; called by muse, mutect2, varscan2
- H2AJ | c.294G>A p.L98= | Silent (SNP) | VAF 24/59 reads (41%) | catalogued as COSV63761758; called by muse, mutect2, varscan2
- HK3 | c.2289C>T p.I763= | Silent (SNP) | VAF 20/50 reads (40%) | catalogued as COSV52836716; called by muse, mutect2, varscan2
- HMGCL | c.316C>T p.L106= | Silent (SNP) | VAF 50/129 reads (39%) | catalogued as COSV52524968; called by muse, mutect2, varscan2
- HMOX2 | c.123C>T p.T41= | Silent (SNP) | VAF 79/135 reads (59%) | catalogued as COSV54859364; called by muse, mutect2, varscan2
- HOXC4 | c.618C>T p.N206= | Silent (SNP) | VAF 9/18 reads (50%) | catalogued as COSV57697665; called by muse, mutect2, varscan2
- HRNR | c.2295C>T p.H765= | Silent (SNP) | VAF 14/70 reads (20%) | catalogued as rs773868367, COSV64262895; called by mutect2, varscan2
- HSPG2 | c.5448C>T p.T1816= | Silent (SNP) | VAF 40/94 reads (43%) | catalogued as COSV65968893; called by muse, mutect2, varscan2
- HYKK | c.639C>T p.T213= | Silent (SNP) | VAF 20/141 reads (14%) | catalogued as COSV66459523; called by muse, mutect2, varscan2
- IGHE | c.726G>A p.V242= | Silent (SNP) | VAF 16/17 reads (94%) | called by muse, mutect2, varscan2
- IL3 | c.381G>A p.R127= | Silent (SNP) | VAF 47/94 reads (50%) | catalogued as COSV57308327; called by muse, mutect2, varscan2
- IRAG1 | c.2154C>T p.S718= | Silent (SNP) | VAF 14/38 reads (37%) | catalogued as COSV70209829; called by muse, mutect2, varscan2
- KCNB1 | c.1719C>T p.P573= | Silent (SNP) | VAF 25/91 reads (27%) | catalogued as COSV65565870; called by muse, mutect2, varscan2
- KIAA1109 | c.10233G>A p.G3411= | Silent (SNP) | VAF 15/42 reads (36%) | called by muse, mutect2, varscan2
- KIF2B | c.705C>T p.I235= | Silent (SNP) | VAF 18/34 reads (53%) | catalogued as COSV52126788; called by muse, mutect2, varscan2
- KIR3DL2 | c.798C>T p.L266= | Silent (SNP) | VAF 25/68 reads (37%) | called by muse, mutect2, varscan2
- LAD1 | c.477G>A p.E159= | Silent (SNP) | VAF 55/95 reads (58%) | catalogued as COSV66211991; called by muse, mutect2, varscan2
- LGI3 | c.468C>T p.F156= | Silent (SNP) | VAF 28/96 reads (29%) | catalogued as COSV60442858; called by muse, mutect2, varscan2
- MAP3K19 | c.990G>A p.L330= | Silent (SNP) | VAF 42/74 reads (57%) | catalogued as COSV59636456; called by muse, mutect2, varscan2
- MBD1 | c.219C>T p.A73= | Silent (SNP) | VAF 4/17 reads (24%) | catalogued as COSV53997858; called by muse, mutect2
- MGA | c.6888C>T p.F2296= (on ENST00000219905 / NM_001164273.1; = p.F2087= on NM_001080541.2) | Silent (SNP) | VAF 11/23 reads (48%) | catalogued as COSV54948266; called by mutect2, varscan2
- MTNR1A | c.435C>T p.L145= | Silent (SNP) | VAF 10/33 reads (30%) | catalogued as COSV56154891; called by muse, mutect2, varscan2
- MUC2 | c.1344C>T p.S448= | Silent (SNP) | VAF 16/31 reads (52%) | called by muse, varscan2
- MYH1 | c.2355G>A p.L785= | Silent (SNP) | VAF 13/27 reads (48%) | catalogued as COSV56843333; called by muse, mutect2, varscan2
- MYH2 | c.4740G>A p.R1580= | Silent (SNP) | VAF 42/101 reads (42%) | catalogued as COSV55431125; called by muse, mutect2, varscan2
- MYH2 | c.2403C>T p.F801= | Silent (SNP) | VAF 20/53 reads (38%) | catalogued as COSV55431132, COSV55436414, COSV55450781; called by muse, mutect2, varscan2
- NBEA | c.4161C>T p.S1387= | Silent (SNP) | VAF 7/13 reads (54%) | catalogued as COSV59758959; called by muse, mutect2, varscan2
- NEDD4 | c.1854G>A p.E618= (on ENST00000508342 / NM_001284338.1; = p.E199= on NM_006154.4) | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as rs766308956, COSV59058262; called by muse, mutect2, varscan2
- NEK9 | c.420C>T p.I140= | Silent (SNP) | VAF 23/56 reads (41%) | catalogued as COSV53129179; called by muse, mutect2, varscan2
- NOVA1 | c.1410G>A p.R470= | Silent (SNP) | VAF 9/27 reads (33%) | catalogued as COSV57471946; called by muse, mutect2, varscan2
- NTRK3 | c.2443T>C p.L815= (on ENST00000360948 / NM_001012338.2; = p.L801= on NM_002530.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 15/58 reads (26%) | catalogued as rs78821883, COSV62295041; called by muse, mutect2, varscan2
- NUP155 | c.1102T>C p.L368= (on ENST00000231498 / NM_153485.3; = p.L309= on NM_004298.4) | Silent (SNP) | VAF 10/18 reads (56%) | catalogued as COSV51526506; called by muse, mutect2, varscan2
- OLFML2B | c.570G>A p.K190= | Silent (SNP) | VAF 63/101 reads (62%) | catalogued as COSV54193630; called by muse, mutect2, varscan2
- OR10A3 | c.72G>A p.Q24= | Silent (SNP) | VAF 7/24 reads (29%) | catalogued as COSV100660235, COSV62459108; called by muse, mutect2, varscan2
- OR2T27 | c.183C>T p.F61= | Silent (SNP) | VAF 12/39 reads (31%) | catalogued as COSV100788078; called by muse, varscan2
- OR51G1 | c.651T>C p.F217= | Silent (SNP) | VAF 8/18 reads (44%) | catalogued as COSV58968316; called by muse, mutect2, varscan2
- OR8D2 | c.660C>T p.F220= | Silent (SNP) | VAF 9/19 reads (47%) | catalogued as rs1031692196, COSV62488000; called by mutect2, varscan2
- ORC3 | c.624C>T p.S208= | Silent (SNP) | VAF 39/86 reads (45%) | catalogued as COSV57638265; called by muse, mutect2, varscan2
- OTOL1 | c.870G>A p.G290= | Silent (SNP) | VAF 10/15 reads (67%) | catalogued as COSV60006855; called by muse, mutect2, varscan2
- P3H3 | c.1911G>A p.R637= | Silent (SNP) | VAF 15/40 reads (38%) | called by muse, mutect2, varscan2
- PABPN1L | c.288C>T p.A96= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as rs1205966596, COSV56350870; called by mutect2, varscan2
- PCDHB7 | c.1107G>A p.R369= | Silent (SNP) | VAF 14/40 reads (35%) | catalogued as COSV50753721; called by muse, mutect2, varscan2
- PHLPP2 | c.192C>T p.L64= | Silent (SNP) | VAF 16/36 reads (44%) | catalogued as rs1353691765, COSV62422386; called by mutect2, varscan2
- PLCZ1 | c.966G>A p.K322= | Silent (SNP) | VAF 15/37 reads (41%) | catalogued as COSV56848583; called by muse, mutect2, varscan2
- PLEC | c.6438G>A p.E2146= (on ENST00000322810 / NM_201380.4; = p.E2036= on NM_000445.5) | Silent (SNP) | VAF 21/33 reads (64%) | catalogued as COSV59601124, COSV59601814; called by muse, mutect2, varscan2
- PNMA1 | c.321C>T p.L107= | Silent (SNP) | VAF 28/72 reads (39%) | catalogued as COSV54092428; called by muse, mutect2, varscan2
- PNPLA4 | c.636C>T p.S212= | Silent (SNP) | VAF 7/9 reads (78%) | catalogued as COSV66853698; called by muse, mutect2, varscan2
- PREX2 | c.132C>T p.F44= | Silent (SNP) | VAF 4/11 reads (36%) | catalogued as rs546875870, COSV55749718; called by mutect2, varscan2
- PRR16 | c.882G>A p.T294= (on ENST00000407149 / NM_001300783.2; = p.T271= on NM_016644.2) | Silent (SNP) | VAF 12/24 reads (50%) | catalogued as rs199619912, COSV65394504; called by mutect2, varscan2
- PRR5 | c.315C>T p.F105= (on ENST00000336985 / NM_181333.4; = p.F96= on NM_015366.4) | Silent (SNP) | VAF 16/32 reads (50%) | catalogued as COSV50058808, COSV50063690; called by muse, mutect2, varscan2
- PSG5 | c.855G>A p.K285= | Silent (SNP) | VAF 37/91 reads (41%) | catalogued as COSV61653427; called by muse, mutect2, varscan2
- RAF1 | c.1275G>A p.E425= | Silent (SNP) | VAF 20/98 reads (20%) | catalogued as COSV52574412; called by muse, mutect2, varscan2
- RFPL2 | c.813C>T p.T271= | Silent (SNP) | VAF 34/52 reads (65%) | catalogued as COSV50711498; called by mutect2, varscan2
- SAMD7 | c.81G>A p.V27= | Silent (SNP) | VAF 38/76 reads (50%) | catalogued as COSV59416869; called by muse, mutect2, varscan2
- SCAMP5 | c.429G>A p.T143= | Silent (SNP) | VAF 184/257 reads (72%) | catalogued as rs778160445, COSV62642807; called by muse, mutect2, varscan2
- SCARB1 | c.528G>A p.V176= | Silent (SNP) | VAF 18/50 reads (36%) | called by mutect2, varscan2
- SIGLEC5 | c.891G>A p.G297= | Silent (SNP) | VAF 35/79 reads (44%) | catalogued as COSV55777260; called by muse, mutect2, varscan2
- SLC16A14 | c.624C>T p.L208= | Silent (SNP) | VAF 16/56 reads (29%) | catalogued as COSV54616631; called by mutect2, varscan2
- SLC26A7 | c.1167C>T p.F389= | Silent (SNP) | VAF 43/72 reads (60%) | catalogued as rs781639714, COSV52586035; called by mutect2, varscan2
- SLC8A2 | c.2136G>T p.G712= | Silent (SNP) | VAF 24/65 reads (37%) | catalogued as COSV52637455; called by muse, mutect2, varscan2
- SLIT3 | c.849C>T p.P283= | Silent (SNP) | VAF 19/46 reads (41%) | catalogued as COSV60591702; called by muse, mutect2, varscan2
- SNX1 | c.597G>A p.E199= | Silent (SNP) | VAF 19/39 reads (49%) | catalogued as rs746166562, COSV56037379; called by muse, mutect2, varscan2
- SNX14 | c.396G>A p.K132= | Silent (SNP) | VAF 38/111 reads (34%) | catalogued as rs181964812; called by muse, mutect2, varscan2
- SOGA1 | c.2127C>T p.L709= | Silent (SNP) | VAF 14/40 reads (35%) | catalogued as rs367609865, COSV52929054; called by mutect2, varscan2
- SPEM2 | c.387C>T p.R129= | Silent (SNP) | VAF 22/51 reads (43%) | catalogued as rs768070648, COSV60366032; called by muse, mutect2, varscan2
- SPTAN1 | c.138C>T p.F46= | Silent (SNP) | VAF 62/69 reads (90%) | catalogued as COSV63985682; called by muse, mutect2, varscan2
- SRRM1 | c.357C>T p.I119= | Silent (SNP) | VAF 61/163 reads (37%) | catalogued as COSV60475060; called by muse, mutect2, varscan2
- TBL3 | c.1551C>T p.F517= | Silent (SNP) | VAF 19/37 reads (51%) | catalogued as COSV60340584; called by muse, mutect2, varscan2
- TCIM | c.66C>T p.I22= | Silent (SNP) | VAF 13/60 reads (22%) | catalogued as COSV59927628; called by muse, varscan2
- TDRD9 | c.3231C>T p.V1077= | Silent (SNP) | VAF 13/29 reads (45%) | called by muse, mutect2, varscan2
- TEX15 | c.2880C>T p.S960= (on ENST00000256246; = p.S1343= on NM_001350162.2) | Silent (SNP) | VAF 52/92 reads (57%) | catalogued as COSV56341231, COSV56350939; called by muse, mutect2, varscan2
- THOC5 | c.1146C>T p.A382= | Silent (SNP) | VAF 47/79 reads (59%) | catalogued as COSV63797580; called by muse, mutect2, varscan2
- TRAF1 | c.1221C>T p.F407= | Silent (SNP) | VAF 45/49 reads (92%) | catalogued as rs1010023920, COSV65867654; called by muse, mutect2
- TRAV3 | c.201G>A p.L67= | Silent (SNP) | VAF 26/59 reads (44%) | called by mutect2, varscan2
- TTN | c.53385G>A p.K17795= (on ENST00000591111; = p.K10371= on NM_003319.4) | Silent (SNP) | VAF 33/61 reads (54%) | catalogued as COSV59874894, COSV60225593; called by muse, mutect2, varscan2
- TUBGCP2 | c.1257C>T p.I419= | Silent (SNP) | VAF 20/27 reads (74%) | called by muse, mutect2, varscan2
- UBR5 | c.7407C>T p.S2469= | Silent (SNP) | VAF 74/258 reads (29%) | catalogued as rs770782554, COSV55279602; called by muse, mutect2, varscan2
- UBTF | c.2145G>A p.E715= | Silent (SNP) | VAF 13/27 reads (48%) | catalogued as COSV57184691; called by muse, mutect2, varscan2
- UGT2B10 | c.618C>T p.F206= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as COSV55318475; called by mutect2, varscan2
- UNC79 | c.2460G>A p.T820= (on ENST00000393151 / NM_001346218.2; = p.T643= on NM_020818.5) | Silent (SNP) | VAF 24/60 reads (40%) | catalogued as rs368534613, COSV56372789; called by mutect2, varscan2
- UROC1 | c.912G>A p.R304= | Silent (SNP) | VAF 22/41 reads (54%) | catalogued as rs267599594, COSV52031041; called by muse, mutect2, varscan2
- UTP6 | c.1167G>A p.L389= | Silent (SNP) | VAF 33/75 reads (44%) | catalogued as COSV55571337; called by muse, mutect2, varscan2
- WNT8B | c.39C>T p.F13= | Silent (SNP) | VAF 24/34 reads (71%) | catalogued as COSV100649150, COSV59324506; called by mutect2, varscan2
- XKR7 | c.924C>T p.F308= | Silent (SNP) | VAF 26/46 reads (57%) | catalogued as rs940513266, COSV101629237, COSV73812872; called by mutect2, varscan2
- ZBTB16 | c.801G>A p.G267= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as rs1157119194, COSV60089030; called by mutect2, varscan2
- ZNF135 | c.807C>T p.P269= (on ENST00000313434 / NM_001289401.2; = p.P281= on NM_003436.4) | Silent (SNP) | VAF 16/47 reads (34%) | catalogued as COSV57880020; called by muse, mutect2, varscan2
- ZNF354B | c.387G>A p.E129= | Silent (SNP) | VAF 16/35 reads (46%) | catalogued as COSV59365037, COSV59366610; called by muse, mutect2, varscan2
- ZNF579 | c.990C>G p.P330= | Silent (SNP) | VAF 14/28 reads (50%) | catalogued as COSV57637147, COSV57638569; called by muse, mutect2, varscan2
- ZNF695 | c.318C>T p.F106= | Silent (SNP) | VAF 116/189 reads (61%) | called by muse, mutect2, varscan2
- ZSCAN29 | c.1818C>T p.G606= | Silent (SNP) | VAF 34/100 reads (34%) | called by mutect2, varscan2
- ZZEF1 | c.4644C>T p.P1548= | Silent (SNP) | VAF 41/98 reads (42%) | catalogued as rs112690569; called by mutect2, varscan2
- AL353804.6 | chrX:73826660 C>T | 3'Flank (SNP) | VAF 32/38 reads (84%) | catalogued as rs1297881448; called by muse, mutect2, varscan2
- BCR | c.1279+17060A>T | Intron (SNP) | VAF 25/86 reads (29%) | called by muse, mutect2, varscan2
- COL11A1 | c.898-252G>A | Intron (SNP) | VAF 46/104 reads (44%) | catalogued as COSV62172257; called by mutect2, varscan2
- HLA-F | chr6:29728015 C>A | 3'Flank (SNP) | VAF 33/89 reads (37%) | catalogued as rs767360928; called by mutect2, varscan2
- LRP5L | n.479C>T | RNA (SNP) | VAF 21/39 reads (54%) | called by muse, mutect2, varscan2
- LRP5L | n.478C>T | RNA (SNP) | VAF 21/40 reads (53%) | catalogued as rs1399890227; called by muse, mutect2, varscan2
- SEZ6L2 | c.2489-190G>A | Intron (SNP) | VAF 32/72 reads (44%) | catalogued as rs764439495, COSV58096980; called by mutect2, varscan2
- SLC25A48 | c.679+161C>T | Intron (SNP) | VAF 13/35 reads (37%) | catalogued as COSV50848029; called by muse, mutect2, varscan2
- TUBB7P | n.1198G>A | RNA (SNP) | VAF 36/86 reads (42%) | catalogued as rs782317070; called by muse, mutect2, varscan2
